CCDI case PBCCRF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/caa56ab4-7d01-4ddc-8da3-923bf1d51fb5

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 19.7 years (7,199 days).

Biospecimens (3 samples)
- Sample 0DOLUT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOLV5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DOLVZ: Tissue type: Tumor; Specimen type: Solid Tissue.
